Surgical pathology report (de-identified scan), TCGA case TCGA-CD-8535, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site ILSBio, specimen TCGA-CD-8535-01A (Primary Tumor).

[page 1 of 5]
HISTORY OF PRESENT ILLNESS

Chief Complaints: Abdominal pain, nausea, vomit

Symptoms: Weakness

Clinical Findings:

Performance Scale (Karnofsky Score):

- ☐ 100 Asymptomatic ☐ 80-90 Symptomatic but Fully Ambulatory ☒ 60-70 Symptomatic, in bed less than 50% of day
☐ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden ☐ 20-30 Bed Ridden

CURRENT MEDICATIONS

Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 2 of 5]
PAST MEDICAL HISTORY

Diagnosis/Disease/Disorder/Injury	Diagnosis Date	Treatment	Status

OB/GYN HISTORY

Menopausal Status ☐ Pre-menopausal ☐ Peri-Menopausal ☐ Post-menopausal	Date of First Menses	# of Pregnancies
	Date of Last Menses	# of Live Births
Birth Control: ☐ Condom ☐ Oral Contraceptive ☐ IUD ☐ Other: _____		☐ Hormone Replacement Therapy: _____

SOCIAL HISTORY

Occupation:		Environmental Hazards:		
Smoking History				
Current Status ☒ YES ☐ NO	TYPE	Packs/day 1 1/2/day	Duration 25 (yrs)	When Quit Still Smoke (yr)
Alcohol Consumption				
Current Status ☒ YES ☐ NO	TYPE	Drinks/day 2 drinks/day	Duration 20 (yrs)	When Quit 2 months ago (yr)
Drug Use				
Current Status ☐ YES ☒ NO	TYPE	Frequency	Duration (yrs)	When Quit (yr)

FAMILY MEDICAL HISTORY

Relative	Diagnosis	Age of Diagnosis

LAB DATA

Test	Result	Test	Result	Date
HIV	☒ Negative ☐ Positive: _____	CEA	☐ Negative ☐ Positive: _____	
Hep B	☒ Negative ☐ Positive: _____	CA 15-3	☐ Negative ☐ Positive: _____	
Hep C	☒ Negative ☐ Positive: _____	CA 19-9	☐ Negative ☐ Positive: _____	
AFP	☐ Negative ☐ Positive: _____	PSA	☐ Negative ☐ Positive: _____	
Other:	☐ Negative ☐ Positive: _____	Other:	☐ Negative ☐ Positive: _____	

B/T Cell Markers:

[page 3 of 5]
DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound		
X-Ray		
CT		
Endoscopy	A tumour was found in the lesser curvature	
MRI		
Biopsy		

CLINICAL DIAGNOSIS	
Preoperative Clinical Diagnosis	
Location of Suspected Involved Lymph Nodes	Location of Suspected Distant Metastasis
Clinical Staging	
T 3 N 1 M 0	Stage: III A

Treatment Information

SURGICAL TREATMENT		
Procedure		
Extended Gastrectomy		
Primary Tumor		
Organ	Detailed Location	Size
Stomach tumor	lesser curvature	10 x 8 x 3 cm
Extension of Tumor		
Lymph Nodes		
Description	Location of Lymph Nodes	# of Lymph Nodes
Palpable, Non-Dissected Lymph Nodes		
Dissected Lymph Nodes		
Distant Metastasis		
Organ	Detailed Location	Size
Surgical Staging		
T 3 N 1 M 0		Stage: III

NEOADJUVANT THERAPY (Chemo, Radiation, Immuno, Hormonal, or Molecular)				
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 4 of 5]
Pathology Form

Specimen Information

SPECIMEN TYPE (# of samples provided)							
Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
4	2	4	2			4	2
Time to LN2		Time to Formalin		Time to LN2			
12 min		13 min					

PATHOLOGICAL DESCRIPTION			
Primary Tumor			
Organ	Size	Extension of Tumor	Distance to NAT
Stomach Tumor	10 x 8 x 3 cm	lesser curvature	6 cm
Lymph Nodes			
Location	# Examined	# Metastasized	
Distant Metastasis			
Organ	Detailed Location	Size	
Pathological Staging			
pT 3 N 0 M 0		Stage: II II	
Notes: Stomach nodes 5 (positive 5, Negative 0)			

[page 5 of 5]
1. Histological pattern:

CELL DISTRIBUTION		+	-	STRUCTURAL PATTERN		+	-
Diffuse			X	Streaming			
Mosaic		X		Storiform			
Necrosis		X		Fibrosis			
Lymphocytic Infiltration		X		Palisading			
Vascular Invasion			X	Cystic Degeneration			
Clusterized		X		Bleeding			
Alveolar Formation			X	Myxoid Change			
Indian File			X	Psamomma/Calcification			

2. Cellular features:

Squamous	+	-	Adenomatous	+	-	Sarcomatous	+	-	Lymphomatous	+	-
Squamous Cell			Glandular cell	X		Round Cell			Large Cell		
Spindle Cell			Cell Stratification	X		Fibroblast			Small Cell		
Keratin			Secretion	X		Osteoblast			RS Cell/RS Like		
Desmosome			Intracyt. Vacuole	X		Lipoblast			Inflam. Cell		
Pearl			Gland formation	X		Myoblast			Plasma Cell		

Otherwise Specified:

D, 75%, D, 70%, D, 70% D, 60% Necrosis 45%

2. Cellular Differentiation:

Well	Moderately	Poor
		X

3. Nuclear Atypia:

Nuclear Appearance		0	I	II	III
Aniso Nucleosis				X	
Hyperchromatism				X	
Nucleolar Prominent				X	
Multinucleated Giant Cell				X	
Mitotic Activity				X	
Nuclear Grade					X

Histological Diagnosis: Poorly differentiated Adenocarcinoma, G

Comments: M, M2. Carcinoma metastasized to LA

Source: NCI Genomic Data Commons file 50b75048-ce7c-468e-af51-2b52aff3a8e9 (TCGA-CD-8535.CBFC5A60-4746-4C09-BF6E-1EB00D509BE5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).